Gene-level copy-number profile of tumor specimen ALCH-B3AB-TTP1-A from ALCHEMIST case ALCH-B3AB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.8 years (21,105 days).
Specimen ALCH-B3AB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d13ff780-c06e-4f07-bab2-11827e134163.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,811 have no estimate.
https://portal.gdc.cancer.gov/files/ed272dfa-a564-44b3-adb5-fe75a0a606a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 239; copy number 1: 2,242; copy number 2: 22,784; copy number 3: 14,081; copy number 4: 15,605; copy number 5: 2,995; copy number 6: 376; copy number 7: 264; copy number 8: 128; copy number 9: 59; copy number 12: 30; copy number 13: 8; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.
- chr1:120,489,860–120,914,238, 9 genes (within-gene range 0–2): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr16:74,332,402–74,368,240, 1 gene (within-gene range 0–2): AC009053.1.
- chr22:38,952,741–38,998,209, 3 genes: APOBEC3A, APOBEC3B, APOBEC3B-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,861 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–151,699,091, 119 genes, copy number 5 (broad region; genes not listed).
- chr1:178,724,306–180,123,890, 41 genes, copy number 5: AL449106.1, RALGPS2, PTPN2P1, SNORA63, ANGPTL1, FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54, AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2, TDRD5, AL359853.2, FAM163A, AL359853.1, LINC02818, TOR1AIP2, AL353708.3, TOR1AIP1, RN7SL230P, AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1, AL390718.1.
- chr1:184,790,724–187,686,628, 44 genes, copy number 5: NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1.
- chr1:201,134,772–202,144,743, 40 genes, copy number 5: TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A.
- chr1:202,193,901–203,024,848, 28 genes, copy number 5: LGR6, UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2, SNORA70, SYT2, AC104463.2, AC104463.1, KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6, MGAT4EP, TUBA5P, ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA, ADIPOR1, CYB5R1, MGAT4FP, AC096632.1, TMEM183A.
- chr1:203,729,581–203,955,780, 11 genes, copy number 5: SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3.
- chr1:206,957,965–207,879,115, 26 genes, copy number 5: FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55, CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2.
- chr3:84,958,989–89,048,434, 35 genes, copy number 5–7 (within-gene range 5–8): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50.
- chr3:129,647,792–129,893,606, 4 genes, copy number 6: TMCC1, RNY3P13, U6, AC083799.1.
- chr3:141,470,634–142,807,888, 33 genes, copy number 5: KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P.
- chr3:167,478,684–184,133,561, 274 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:195,274,745–198,123,232, 112 genes, copy number 5 (broad region; genes not listed).
- chr4:51,843,000–61,153,962, 141 genes, copy number 5–12 (broad region; genes not listed).
- chr5:64,404,512–69,558,104, 90 genes, copy number 5 (broad region; genes not listed).
- chr6:34,466,061–39,115,186, 121 genes, copy number 5–7 (broad region; genes not listed).
- chr6:53,196,720–58,438,364, 75 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:603,185–1,621,405, 31 genes, copy number 5: PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2.
- chr7:44,367,140–44,920,329, 19 genes, copy number 5: AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1.
- chr9:120,952,335–121,500,027, 11 genes, copy number 5 (within-gene range 4–5): C5, CNTRL, RAB14, RN7SL181P, GSN, AL513122.1, AL513122.2, GSN-AS1, STOM, AL359644.1, GGTA1.
- chr9:129,883,693–130,140,169, 5 genes, copy number 5 (within-gene range 4–5): AL158207.1, FNBP1, AL158207.2, AL136141.1, GPR107.
- chr9:135,907,812–137,892,570, 127 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:65,213,840–65,561,607, 27 genes, copy number 5–6: SLC22A20P, POLA2, AP000944.5, AP000944.7, CDC42EP2, DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1.
- chr14:19,719,015–47,675,605, 687 genes, copy number 5–6 (broad region; genes not listed).
- chr17:47,522,942–47,685,505, 4 genes, copy number 5 (within-gene range 3–5): NPEPPS, Y_RNA, AC025682.1, KPNB1.
- chr17:76,142,465–76,271,298, 4 genes, copy number 5 (within-gene range 4–5): RNF157, ATP5MGP6, ATF4P3, UBALD2.
- chr18:45,034–122,219, 7 genes, copy number 6: AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078.
- chr18:1,883,524–12,929,643, 239 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr18:14,877,611–37,232,172, 268 genes, copy number 5 (broad region; genes not listed).
- chr18:37,657,135–80,247,514, 573 genes, copy number 5 (broad region; genes not listed).
- chr19:21,082,159–21,196,053, 5 genes, copy number 5 (within-gene range 2–5): ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10.
- chr19:27,638,483–30,038,181, 57 genes, copy number 5–6: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr19:31,787,148–35,813,299, 166 genes, copy number 6–13 (broad region; genes not listed).
- chr19:38,211,006–38,899,862, 39 genes, copy number 7 (within-gene range 4–7): DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2.
- chr19:39,385,629–39,846,379, 36 genes, copy number 5–8 (within-gene range 4–8): PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL.
- chr19:44,326,555–46,850,846, 144 genes, copy number 5–8 (broad region; genes not listed).
- chr19:52,130,548–52,367,778, 16 genes, copy number 5 (within-gene range 2–5): AC011468.2, AC011468.3, RPL37P23, ZNF836, AC010320.1, PPP2R1A, MIR6801, AC010320.2, AC010320.5, Y_RNA, ZNF766, MIR643, AC010320.3, ZNF480, AC010320.4, ZNF610.
- chr19:54,738,513–55,603,138, 69 genes, copy number 6 (broad region; genes not listed).
- chr22:30,331,988–31,530,634, 62 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr22:40,824,535–41,075,239, 10 genes, copy number 6: ST13, XPNPEP3, DNAJB7, Metazoa_SRP, RNU6-379P, RBX1, Y_RNA, AL080243.2, Y_RNA, AL080243.1.
- chr22:44,172,956–46,054,144, 47 genes, copy number 5 (within-gene range 4–5): PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34.

Autosomal genes at a single copy (total copy number 1): 2,238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
